Somatic mutation profile of tumor specimen 0DLJX7 from CCDI case PBBZEJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.4 years (511 days).
Specimen 0DLJX7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 820f4856-fffd-462d-b83f-d4e494a7e14c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLJWM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d022d9cd-15ac-40cd-986c-a302b099cb2a

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Nonsense Mutation 3, Intron 2, Silent 2, Splice Site 1, Frame Shift Del 1, RNA 1, Splice Region 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 316/654 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- PCCB | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 140/354 reads (40%) | catalogued as rs186031457, CM083012, COSV52443287; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP7B | c.4187C>T p.T1396M | Missense Mutation (SNP) | VAF 43/912 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.776); catalogued as rs528603867, COSV54434713, COSV54434723; called by muse, mutect2
- DNAH12 | c.5398C>T p.R1800* (on ENST00000351747; = p.R1819* on NM_001366028.2) | Nonsense Mutation (SNP) | VAF 21/475 reads (4%) | catalogued as rs1035349999, COSV61059035; called by muse, mutect2
- NMT2 | c.1338G>C p.S446= | Splice Region (SNP) | VAF 35/310 reads (11%) | catalogued as COSV65381589, COSV65383213; called by muse, mutect2, varscan2
- PAPOLA | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 61/113 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs764473731, COSV53480186; called by muse, mutect2, varscan2
- SOX5 | c.704G>C p.R235P | Missense Mutation (SNP) | VAF 145/650 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58626585; called by muse, mutect2, varscan2
- STXBP5L | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 16/307 reads (5%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.985); catalogued as rs1175373053; called by muse, mutect2
- WDR87 | c.4675C>G p.Q1559E | Missense Mutation (SNP) | VAF 111/431 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1198638956, COSV100383638; called by muse, mutect2, varscan2
- BSN | c.7058_7065del p.G2353Efs*51 | Frame Shift Del (DEL) | VAF 125/346 reads (36%) | called by mutect2, pindel, varscan2
- COL11A1 | c.3978+2T>C p.X1326_splice | Splice Site (SNP) | VAF 14/208 reads (7%) | called by muse, mutect2
- CYP2C18 | c.361A>T p.K121* | Nonsense Mutation (SNP) | VAF 167/433 reads (39%) | called by muse, mutect2, varscan2
- LARP4B | c.1656C>A p.N552K | Missense Mutation (SNP) | VAF 162/396 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- LBHD1 | c.598C>T p.P200S (on ENST00000431002 / NM_001367940.1; = p.P174S on NM_024099.3) | Missense Mutation (SNP) | VAF 233/250 reads (93%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- SLIT3 | c.3238G>A p.A1080T | Missense Mutation (SNP) | VAF 280/606 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPTAN1 | c.4620G>T p.M1540I | Missense Mutation (SNP) | VAF 23/516 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- STXBP5L | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 16/297 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2
- TNFRSF11B | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 71/285 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZNF821 | c.1192C>A p.L398M (on ENST00000425432 / NM_001376297.1; = p.L356M on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/358 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- HNMT | c.699T>C p.G233= | Silent (SNP) | VAF 170/521 reads (33%) | called by muse, mutect2, varscan2
- JUND | c.78G>T p.A26= | Silent (SNP) | VAF 141/458 reads (31%) | called by muse, mutect2, varscan2
- AC021218.1 | n.997G>T | RNA (SNP) | VAF 129/265 reads (49%) | catalogued as rs772470808; called by muse, mutect2, varscan2
- CRACR2A | chr12:3644606 T>C | 3'Flank (SNP) | VAF 104/432 reads (24%) | catalogued as rs993501249; called by muse, mutect2, varscan2
- PPT1 | c.124+60_124+67dup | Intron (INS) | VAF 38/97 reads (39%) | called by mutect2, varscan2
- REV3L | c.8605-88A>G | Intron (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2
- SYCE3 | c.*23G>T | 3'UTR (SNP) | VAF 173/391 reads (44%) | called by muse, mutect2, varscan2
